Somatic mutation profile of tumor specimen ALCH-B46A-TTP1-A (aliquot ALCH-B46A-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B46A, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.6 years (21,777 days).
Specimen ALCH-B46A-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec99e82c-ffbf-4628-9562-4276252e5fa9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B46A-NB1-A (Blood Derived Normal), aliquot ALCH-B46A-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/645faf81-1aa8-48ff-b402-5a2ed20af8db

The open-access MAF lists 131 somatic variants for this specimen: 91 protein-altering or splice-affecting, 27 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 27, Nonsense Mutation 9, Intron 7, Frame Shift Del 6, Splice Site 6, 3'UTR 2, Splice Region 1, 3'Flank 1, Frame Shift Ins 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 156/309 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC2 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs138121128; called by muse, mutect2, varscan2
- ARMC4 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV59476541; called by muse, mutect2, varscan2
- BCO2 | c.1681C>T p.R561* | Nonsense Mutation (SNP) | VAF 40/210 reads (19%) | catalogued as rs746511655; called by muse, mutect2, varscan2
- CCDC62 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as rs780033896, COSV53433629; called by muse, mutect2, varscan2
- DIDO1 | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.182); catalogued as COSV99824355; called by muse, mutect2, varscan2
- DNAAF4 | c.951A>G p.I317M | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1416987714; called by muse, mutect2, varscan2
- DVL3 | c.841A>G p.I281V | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as rs1266047392, COSV100493595; called by muse, mutect2, varscan2
- EMX2 | c.727C>A p.P243T | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.13); catalogued as COSV71294442; called by muse, mutect2, varscan2
- GRM8 | c.1592G>T p.G531V | Missense Mutation (SNP) | VAF 57/263 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100285091, COSV58800535; called by muse, mutect2, varscan2
- HLX | c.1102A>G p.S368G | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV100854557; called by muse, mutect2, varscan2
- IGSF11 | c.421T>A p.L141I (on ENST00000393775 / NM_001015887.3; = p.L140I on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as rs759532372, COSV61170162; called by muse, mutect2, varscan2
- KDM5C | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64763044; called by muse, mutect2
- LCE1A | c.65C>A p.P22H | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.998); catalogued as COSV58728222; called by muse, mutect2, varscan2
- MACF1 | c.20701C>T p.R6901W (on ENST00000372915; = p.R4946W on NM_012090.5) | Missense Mutation (SNP) | VAF 21/175 reads (12%) | catalogued as rs776122438; called by muse, mutect2, varscan2
- MMADHC | c.800A>G p.H267R | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753424109, COSV57573957; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH1 | c.2514C>G p.F838L | Missense Mutation (SNP) | VAF 78/314 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV56858994; called by muse, mutect2, varscan2
- NCAPD3 | c.1991A>G p.Q664R | Missense Mutation (SNP) | VAF 63/224 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs1206573855; called by muse, mutect2, varscan2
- OR6F1 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); catalogued as COSV100128972; called by muse, mutect2, varscan2
- PKHD1L1 | c.508A>T p.T170S | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.817); catalogued as COSV65749411; called by muse, mutect2, varscan2
- PTPRC | c.1974G>A p.Q658= | Splice Region (SNP) | VAF 114/481 reads (24%) | catalogued as COSV100723152, COSV100723161; called by muse, mutect2, varscan2
- SAMD9L | c.828G>T p.E276D | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV59080303; called by muse, mutect2, varscan2
- SETD2 | c.1535C>G p.S512* | Nonsense Mutation (SNP) | VAF 23/93 reads (25%) | catalogued as COSV57437123; called by muse, mutect2, varscan2
- SOX17 | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV52026102; called by mutect2, varscan2
- STXBP5L | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 69/280 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs201266367; called by muse, mutect2, varscan2
- TNC | c.1370A>T p.E457V | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs1367300613; called by muse, mutect2, varscan2
- TRIM10 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as COSV64990234; called by muse, mutect2, varscan2
- TTC33 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 15/250 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61802544; called by muse, mutect2
- VLDLR | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.342); catalogued as rs748227215; called by muse, mutect2, varscan2
- ACTN2 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 97/334 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ADAMTS19 | c.1162G>T p.E388* | Nonsense Mutation (SNP) | VAF 34/219 reads (16%) | called by muse, mutect2, varscan2
- AGRN | c.3014C>G p.P1005R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- APBB2 | c.1759G>T p.V587F (on ENST00000295974 / NM_001166050.2; = p.V588F on NM_004307.2) | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARID1A | c.4000C>T p.Q1334* | Nonsense Mutation (SNP) | VAF 17/94 reads (18%) | called by mutect2, varscan2
- ARRDC3 | c.1109A>G p.D370G | Missense Mutation (SNP) | VAF 64/462 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- BCL6B | c.626C>A p.A209E | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.093); called by muse, varscan2
- BIN2 | c.82-1G>T p.X28_splice | Splice Site (SNP) | VAF 56/137 reads (41%) | called by muse, mutect2, varscan2
- BOD1L2 | c.52del p.R18Gfs*55 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- CATSPER2 | c.697del p.V233Sfs*9 | Frame Shift Del (DEL) | VAF 59/222 reads (27%) | called by mutect2, varscan2
- CCDC102B | c.1094A>T p.K365M | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- CEP152 | c.3628del p.I1210Lfs*12 | Frame Shift Del (DEL) | VAF 26/87 reads (30%) | called by mutect2, pindel
- CEP295 | c.2221A>T p.R741W | Missense Mutation (SNP) | VAF 78/305 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- COL6A6 | c.1211T>G p.L404R | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNHD1 | c.5916G>T p.L1972F | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- ERAL1 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.761); called by muse, mutect2
- FRG2 | c.679A>G p.M227V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); called by mutect2, varscan2
- GALE | c.691G>C p.D231H | Missense Mutation (SNP) | VAF 57/405 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- GBF1 | c.2182C>G p.L728V (on ENST00000369983 / NM_001377137.1; = p.L727V on NM_004193.3) | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GLI1 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 57/252 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GLI3 | c.3391G>T p.A1131S | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRXCR2 | c.420T>A p.D140E | Missense Mutation (SNP) | VAF 68/346 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- H2AP | c.273C>G p.N91K | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- HAS1 | c.1205C>A p.T402N | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HCCS | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 93/491 reads (19%) | called by muse, mutect2, varscan2
- HJV | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.608); called by muse, varscan2
- HMCES | c.1035A>C p.E345D | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, varscan2
- HMCES | c.1041_1044del p.A348Sfs*28 | Frame Shift Del (DEL) | VAF 37/163 reads (23%) | called by pindel, varscan2
- IGKV4-1 | c.103_104del p.L35Gfs*21 | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | called by pindel, varscan2
- IRS4 | c.1820G>A p.G607E | Missense Mutation (SNP) | VAF 69/288 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KDM1A | c.2047A>T p.S683C | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KIF5A | c.2661G>T p.M887I | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- KIT | c.757-1G>A p.X253_splice | Splice Site (SNP) | VAF 69/284 reads (24%) | called by muse, mutect2, varscan2
- KSR1 | c.2455C>T p.R819C (on ENST00000644974 / NM_001367810.1; = p.R704C on NM_014238.2) | Missense Mutation (SNP) | VAF 41/288 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- LRP5 | c.1911G>T p.M637I | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2
- MAMDC4 | c.3358C>A p.L1120M (on ENST00000445819; = p.L1041M on NM_206920.3) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MXRA5 | c.7486A>T p.T2496S | Missense Mutation (SNP) | VAF 61/244 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NPAS3 | c.994A>G p.M332V (on ENST00000356141 / NM_001164749.2; = p.M300V on NM_022123.3) | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- NR6A1 | c.347G>T p.R116L (on ENST00000487099 / NM_033334.4; = p.R112L on NM_001489.5) | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAX4 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- PCDHGB2 | c.1600G>T p.A534S | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDE6C | c.481-1G>A p.X161_splice | Splice Site (SNP) | VAF 62/200 reads (31%) | called by muse, mutect2, varscan2
- PLA2G6 | c.460A>T p.T154S | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- PMFBP1 | c.637-1G>T p.X213_splice | Splice Site (SNP) | VAF 22/83 reads (27%) | called by muse, mutect2, varscan2
- PRPS2 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 43/403 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- RAB40A | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 42/196 reads (21%) | called by muse, mutect2, varscan2
- RUBCNL | c.1081T>C p.S361P | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.129); called by muse, mutect2
- RYR1 | c.9179A>G p.D3060G | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- SERPINA3 | c.1068+1G>C p.X356_splice | Splice Site (SNP) | VAF 83/303 reads (27%) | called by muse, mutect2, varscan2
- SETD2 | c.4744G>T p.E1582* | Nonsense Mutation (SNP) | VAF 25/96 reads (26%) | called by muse, mutect2, varscan2
- SIN3B | c.582+1G>A p.X194_splice | Splice Site (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2
- SVIL | c.2587G>A p.V863M (on ENST00000355867 / NM_021738.3; = p.V437M on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- TCEA2 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- TEX13C | c.876C>A p.C292* | Nonsense Mutation (SNP) | VAF 23/76 reads (30%) | called by muse, mutect2, varscan2
- TFAP2A | c.847C>T p.R283C (on ENST00000482890; = p.R275C on NM_001032280.3) | Missense Mutation (SNP) | VAF 52/411 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TPTE | c.1499C>G p.T500R (on ENST00000618007 / NM_199261.4; = p.T482R on NM_199259.4) | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRA2B | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- TTC30B | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 32/461 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2
- ZFP42 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZMYM4 | c.3896del p.G1299Vfs*26 | Frame Shift Del (DEL) | VAF 32/179 reads (18%) | called by mutect2, pindel, varscan2
- ZNF469 | c.8465C>A p.P2822Q (on ENST00000437464; = p.P2850Q on NM_001367624.2) | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.142); called by muse, mutect2
- ZNF662 | c.846dup p.K283Efs*4 | Frame Shift Ins (INS) | VAF 24/127 reads (19%) | called by mutect2, pindel, varscan2
- ABHD8 | c.225G>A p.L75= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as rs1198619549; called by muse, mutect2, varscan2
- BRINP3 | c.1966C>A p.R656= | Silent (SNP) | VAF 80/352 reads (23%) | catalogued as COSV66522561, COSV66523061; called by muse, mutect2, varscan2
- BRINP3 | c.1965C>A p.S655= | Silent (SNP) | VAF 76/340 reads (22%) | called by muse, mutect2, varscan2
- CASR | c.105G>T p.G35= | Silent (SNP) | VAF 104/357 reads (29%) | called by muse, mutect2, varscan2
- FGF3 | c.510C>T p.R170= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV61926702; called by muse, mutect2, varscan2
- GLI3 | c.3873C>A p.G1291= | Silent (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- HAS1 | c.1206C>A p.T402= | Silent (SNP) | VAF 27/133 reads (20%) | catalogued as rs773111716, COSV55788880; called by muse, mutect2, varscan2
- HJURP | c.780C>T p.I260= | Silent (SNP) | VAF 15/124 reads (12%) | called by muse, mutect2, varscan2
- HSPG2 | c.643C>T p.L215= | Silent (SNP) | VAF 43/148 reads (29%) | called by muse, mutect2, varscan2
- LGI2 | c.1128G>A p.A376= | Silent (SNP) | VAF 55/176 reads (31%) | catalogued as rs756467143, COSV66122507; called by muse, mutect2, varscan2
- MAGI2 | c.2193A>T p.S731= | Silent (SNP) | VAF 72/258 reads (28%) | called by muse, mutect2, varscan2
- MUC4 | c.7725C>G p.T2575= | Silent (SNP) | VAF 35/188 reads (19%) | catalogued as rs768320995; called by muse, mutect2, varscan2
- MYO15A | c.10452C>T p.D3484= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs747803954, COSV52756552; called by muse, mutect2, varscan2
- NAT10 | c.2118G>A p.L706= | Silent (SNP) | VAF 26/132 reads (20%) | called by muse, mutect2, varscan2
- NFE2L3 | c.57C>T p.L19= | Silent (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2
- NID2 | c.249C>A p.I83= | Silent (SNP) | VAF 51/213 reads (24%) | called by muse, mutect2, varscan2
- NUP54 | c.363G>T p.A121= | Silent (SNP) | VAF 72/350 reads (21%) | called by muse, mutect2
- OR10A2 | c.582C>A p.V194= | Silent (SNP) | VAF 40/148 reads (27%) | catalogued as COSV56300244; called by muse, mutect2, varscan2
- OR1A2 | c.364C>A p.R122= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV67936383; called by muse, mutect2
- OR1C1 | c.522C>A p.I174= | Silent (SNP) | VAF 71/289 reads (25%) | called by muse, mutect2, varscan2
- OR2L8 | c.225C>A p.T75= | Silent (SNP) | VAF 80/286 reads (28%) | called by muse, mutect2, varscan2
- OR6K6 | c.144G>T p.A48= (on ENST00000368144; = p.A24= on NM_001005184.1) | Silent (SNP) | VAF 62/242 reads (26%) | catalogued as rs147601748, COSV63744717, COSV63744838; called by muse, mutect2, varscan2
- SGCD | c.100C>T p.L34= (on ENST00000435422 / NM_001128209.2; = p.L35= on NM_000337.5) | Silent (SNP) | VAF 44/258 reads (17%) | called by muse, mutect2, varscan2
- SVOP | c.534G>T p.V178= | Silent (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
- TRPC5 | c.255C>A p.I85= | Silent (SNP) | VAF 43/221 reads (19%) | called by muse, mutect2, varscan2
- ZBTB4 | c.2166A>G p.T722= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs780307068; called by muse, mutect2, varscan2
- ZMAT3 | c.198A>G p.L66= | Silent (SNP) | VAF 68/276 reads (25%) | catalogued as rs944699485; called by muse, mutect2, varscan2
- BAALC-AS2 | n.328G>T | RNA (SNP) | VAF 82/309 reads (27%) | called by muse, mutect2, varscan2
- BOC | c.667+233C>A | Intron (SNP) | VAF 38/146 reads (26%) | called by muse, mutect2, varscan2
- C12orf57 | chr12:6943660 del TAAG | 5'Flank (DEL) | VAF 20/118 reads (17%) | catalogued as rs1407437709; called by pindel, varscan2
- CENPX | c.-17G>T | 5'UTR (SNP) | VAF 19/92 reads (21%) | catalogued as rs765814404; called by muse, mutect2, varscan2
- GBGT1 | c.225-32G>T | Intron (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2
- MATR3 | c.*1576dup | 3'UTR (INS) | VAF 25/182 reads (14%) | called by mutect2, varscan2
- MEX3B | c.256+121A>T | Intron (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- MPC1 | c.76-120G>A | Intron (SNP) | VAF 33/76 reads (43%) | called by muse, mutect2, varscan2
- NRG1 | c.1269-496G>A | Intron (SNP) | VAF 21/222 reads (9%) | called by muse, mutect2, varscan2
- SSR2 | c.-1+11del | Intron (DEL) | VAF 17/106 reads (16%) | called by mutect2, pindel, varscan2
- SSX5 | c.69+185C>A | Intron (SNP) | VAF 43/134 reads (32%) | catalogued as COSV100308859, COSV61255297; called by muse, mutect2, varscan2
- SYT14 | chr1:210163381 C>G | 3'Flank (SNP) | VAF 10/349 reads (3%) | called by muse, mutect2
- ZNF99 | c.*698G>T | 3'UTR (SNP) | VAF 77/368 reads (21%) | catalogued as rs376059510; called by muse, varscan2
